Somatic mutation profile of tumor specimen TCGA-55-8514-01A (aliquot TCGA-55-8514-01A-11D-2393-08) from TCGA case TCGA-55-8514, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.1 years (25,608 days).
Specimen TCGA-55-8514-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3cd692a-a45a-4c6e-8b4d-f753e057fe92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8514-10A (Blood Derived Normal), aliquot TCGA-55-8514-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32f5e290-97c3-4945-9eb5-2448aaebd9c0

The open-access MAF lists 312 somatic variants for this specimen: 240 protein-altering or splice-affecting, 62 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 62, Nonsense Mutation 18, Frame Shift Del 11, Splice Site 8, Intron 4, Splice Region 3, RNA 3, Frame Shift Ins 2, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.1010G>C p.R337P | Missense Mutation (SNP) | VAF 11/24 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.3283G>T p.V1095L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0.006); catalogued as COSV99447836; called by muse, mutect2, varscan2
- ACSL4 | c.1822G>T p.D608Y (on ENST00000340800 / NM_022977.2; = p.D567Y on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV100539130; called by muse, mutect2, varscan2
- ACY3 | c.660G>T p.M220I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV99663184; called by muse, mutect2, varscan2
- ADAM15 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV55063739, COSV99665391; called by muse, varscan2
- AFAP1L1 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780653431, COSV99696166, COSV99696183; called by muse, mutect2, varscan2
- AHI1 | c.1343A>T p.E448V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99663842; called by muse, mutect2
- AHNAK2 | c.11947C>T p.P3983S | Missense Mutation (SNP) | VAF 199/345 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV100319099; called by muse, mutect2, varscan2
- AHNAK2 | c.3383G>T p.S1128I | Missense Mutation (SNP) | VAF 144/284 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.169); catalogued as COSV100319100; called by muse, varscan2
- AK7 | c.43A>T p.I15F | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.024); catalogued as COSV99967576; called by muse, mutect2, varscan2
- AL592490.1 | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV101308295; called by muse, mutect2, varscan2
- AMER2 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.029); catalogued as COSV100766401; called by muse, mutect2, varscan2
- ARHGEF11 | c.3154G>T p.G1052C | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100169019; called by muse, mutect2, varscan2
- ATP13A2 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); catalogued as rs768327980, COSV100454487; called by muse, mutect2, varscan2
- ATRIP | c.2016G>T p.L672F | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.044); catalogued as COSV99604207; called by muse, mutect2, varscan2
- BEST1 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.55); catalogued as COSV100077436; called by muse, mutect2, varscan2
- BHMT2 | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 76/142 reads (54%) | catalogued as COSV99670307; called by muse, mutect2, varscan2
- C12orf71 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV101460564; called by muse, mutect2, varscan2
- C2CD5 | c.281A>T p.D94V | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100449084; called by muse, mutect2, varscan2
- CARMIL2 | c.654G>A p.W218* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100576352; called by muse, mutect2, varscan2
- CBLN4 | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50354530, COSV99290779; called by muse, mutect2, varscan2
- CCDC17 | c.1414T>A p.L472M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100602033; called by muse, mutect2, varscan2
- CCDC34 | c.434G>T p.W145L | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100156710; called by muse, mutect2, varscan2
- CCDC34 | c.433T>A p.W145R | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100156711, COSV100156749; called by muse, mutect2, varscan2
- CCIN | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.761); catalogued as COSV100631965; called by muse, mutect2, varscan2
- CDC42BPA | c.4223A>T p.Q1408L (on ENST00000334218 / NM_001366019.2; = p.Q1395L on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV100506994; called by muse, mutect2, varscan2
- CEACAM20 | c.1063T>C p.S355P | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV100387050; called by muse, mutect2, varscan2
- CELSR1 | c.5219G>T p.R1740L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99420241; called by muse, mutect2, varscan2
- CENPI | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99515899; called by muse, mutect2, varscan2
- CEP85L | c.1651A>T p.K551* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100874390; called by muse, mutect2
- CHRNB2 | c.261G>T p.W87C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100872694; called by muse, mutect2, varscan2
- CLTCL1 | c.2833C>A p.R945S | Missense Mutation (SNP) | VAF 81/291 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV99594469, COSV99595985; called by muse, mutect2, varscan2
- CNR2 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as COSV100991617; called by muse, mutect2, varscan2
- CNTNAP5 | c.3610G>T p.D1204Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); catalogued as COSV101444281; called by muse, mutect2, varscan2
- COL19A1 | c.1229G>A p.R410K | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as COSV100507618; called by muse, mutect2, varscan2
- COL5A1 | c.4411G>A p.G1471S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750864661, COSV65668331; called by muse, mutect2, varscan2
- CSF2RB | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99454519; called by muse, mutect2, varscan2
- CSMD1 | c.4675G>T p.E1559* (on ENST00000520002; = p.E1558* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100154260; called by muse, mutect2
- CSMD2 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | catalogued as COSV53974375; called by muse, mutect2, varscan2
- CSMD3 | c.9136C>G p.P3046A (on ENST00000297405 / NM_001363185.1; = p.P2877A on NM_052900.3) | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52271263; called by muse, mutect2, varscan2
- CTSS | c.584A>T p.N195I | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100935044; called by muse, mutect2, varscan2
- CUBN | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as rs1461982823, COSV100913636; called by muse, mutect2, varscan2
- CYTH1 | c.964-2A>T p.X322_splice | Splice Site (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100739522; called by muse, mutect2, varscan2
- DCTN5 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100266098; called by muse, mutect2, varscan2
- DLX5 | c.18C>A p.D6E | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.043); catalogued as COSV99756714; called by muse, mutect2, varscan2
- DNAH9 | c.7402A>G p.M2468V | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs754756657, COSV99308399; called by muse, mutect2, varscan2
- DNAH9 | c.8195A>T p.Q2732L | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV52376303, COSV99308402; called by muse, mutect2, varscan2
- DPAGT1 | c.141C>G p.N47K | Missense Mutation (SNP) | VAF 130/356 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.382); catalogued as COSV100830794; called by muse, mutect2, varscan2
- EGR4 | c.1111G>T p.A371S (on ENST00000545030; = p.A268S on NM_001965.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV101474274, COSV71531928; called by muse, mutect2, varscan2
- EHD3 | c.785T>A p.L262H | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100434898; called by muse, mutect2, varscan2
- EIF2S2 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66621371, COSV66621396; called by muse, mutect2, varscan2
- EIF3J | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV56008400, COSV99970803; called by muse, mutect2, varscan2
- EPB41 | c.1147G>C p.D383H (on ENST00000343067 / NM_001166005.2; = p.D174H on NM_004437.4) | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544599235, COSV58054436; called by muse, mutect2, varscan2
- ERMARD | c.391T>C p.S131P | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100824943; called by muse, mutect2
- ESRRG | c.338A>T p.Q113L | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100753984; called by muse, mutect2, varscan2
- ETV3L | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs1003386769, COSV101485623; called by muse, mutect2, varscan2
- EYS | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV100677217, COSV60984721; called by muse, mutect2, varscan2
- F13B | c.1172-1G>C p.X391_splice | Splice Site (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100803315, COSV100803482; called by muse, mutect2, varscan2
- FAM110B | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64065143; called by muse, mutect2, varscan2
- FAM153B | c.271C>T p.R91W (on ENST00000253490; = p.R14W on NM_001265615.1) | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.835); catalogued as rs759541571; called by muse, mutect2
- FAM47A | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV100649940, COSV100650107; called by muse, mutect2, varscan2
- FAM47B | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100264677; called by muse, mutect2, varscan2
- FAM83B | c.1908C>A p.N636K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100175074; called by muse, mutect2, varscan2
- FAT1 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1382265220, COSV101499664; called by muse, mutect2, varscan2
- FBN1 | c.650G>T p.W217L | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM154798, COSV100356504; called by muse, mutect2, varscan2
- FCMR | c.10T>A p.W4R | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV100892931; called by muse, mutect2, varscan2
- FIG4 | c.734A>G p.D245G | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1370834389, COSV100020307; called by muse, mutect2, varscan2
- GNAS | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.22); catalogued as rs764619253, COSV100007781; called by muse, mutect2, varscan2
- GPR158 | c.1789T>C p.C597R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100894358; called by muse, mutect2, varscan2
- HAUS7 | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100444349; called by muse, mutect2, varscan2
- HCFC1 | c.3682C>A p.L1228I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100129994; called by muse, mutect2
- HEPH | c.2128A>T p.R710W (on ENST00000343002; = p.R443W on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1359812600, COSV100295821; called by muse, mutect2, varscan2
- HHIPL2 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 59/357 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as rs753929029, COSV58564406; called by muse, mutect2, varscan2
- HMGB3 | c.393G>T p.W131C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100308638; called by muse, mutect2, varscan2
- HMGCS1 | c.1182G>A p.P394= | Splice Region (SNP) | VAF 42/96 reads (44%) | catalogued as rs182480352; called by muse, mutect2, varscan2
- HS3ST3A1 | c.721G>T p.V241L | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV52378667, COSV99404539; called by muse, mutect2, varscan2
- HSD17B11 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs762809916, COSV100839639; called by muse, mutect2, varscan2
- IDH3G | c.623C>A p.A208E | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99473144, COSV99473452; called by muse, mutect2, varscan2
- IFNA2 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 82/429 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101206998, COSV66505870; called by muse, mutect2, varscan2
- ILF3 | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99140353; called by muse, mutect2
- INS-IGF2 | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as CM101404, COSV99171169; called by muse, mutect2, varscan2
- INS-IGF2 | c.16C>G p.R6G | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.13); catalogued as rs121908278, CM082897, COSV51747114, COSV99171170; called by muse, mutect2, varscan2
- IRS4 | c.3476C>A p.S1159Y | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV100929759; called by muse, mutect2, varscan2
- KCNH5 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.264); catalogued as rs756506083, COSV100525977; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1549L | c.4708G>T p.A1570S (on ENST00000321505; = p.A1867S on NM_012194.3) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.369); catalogued as COSV100382502, COSV58581128; called by muse, mutect2, varscan2
- KIF2C | c.760-1G>T p.X254_splice | Splice Site (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100945886; called by muse, mutect2, varscan2
- KLK10 | c.735G>T p.W245C | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100011317; called by muse, mutect2, varscan2
- KMT2C | c.5575C>T p.P1859S | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.197); catalogued as COSV100077069; called by muse, mutect2, varscan2
- KMT2C | c.4091A>G p.Q1364R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100077073; called by muse, mutect2, varscan2
- KRTAP12-2 | c.325A>T p.S109C | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.228); catalogued as COSV100555627; called by muse, mutect2, varscan2
- LHX2 | c.639C>A p.Y213* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV101010096; called by muse, mutect2, varscan2
- LMOD1 | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs576061893, COSV100939288; called by muse, mutect2, varscan2
- LNPK | c.65A>T p.D22V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99770508; called by muse, mutect2, varscan2
- LPA | c.4601A>G p.H1534R | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100308160; called by muse, mutect2, varscan2
- LPCAT2 | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.108); catalogued as rs1418437420; called by muse, mutect2, varscan2
- LRP1B | c.13537G>T p.G4513C | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV101261601; called by muse, mutect2, varscan2
- LRRC32 | c.794del p.P265Rfs*6 | Frame Shift Del (DEL) | VAF 44/168 reads (26%) | catalogued as COSV52631823; called by mutect2, pindel, varscan2
- LRRC36 | c.876G>T p.L292F | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.441); catalogued as COSV99339174; called by muse, mutect2, varscan2
- MAGEA12 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV100757094, COSV63295369; called by muse, mutect2, varscan2
- MAGEA4 | c.944A>T p.E315V | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV99367738; called by muse, mutect2, varscan2
- MAGEB6B | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 51/112 reads (46%) | catalogued as COSV101301707; called by muse, mutect2, varscan2
- MARCHF3 | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100428184; called by muse, mutect2, varscan2
- MED12 | c.5314C>A p.P1772T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100380166, COSV61345551; called by muse, mutect2, varscan2
- METTL3 | c.1368T>G p.I456M | Missense Mutation (SNP) | VAF 103/237 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99398655; called by muse, mutect2, varscan2
- MGAT3 | c.820C>A p.L274M | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.709); catalogued as COSV100362088; called by muse, mutect2, varscan2
- MICAL3 | c.5810G>T p.R1937L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767055189, COSV99349631; called by muse, mutect2, varscan2
- MMP16 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54175380; called by muse, mutect2, varscan2
- MOS | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.941); catalogued as COSV100323035; called by muse, mutect2, varscan2
- MOSPD2 | c.1185G>A p.G395= | Splice Region (SNP) | VAF 10/140 reads (7%) | catalogued as COSV100996953; called by muse, mutect2
- MOSPD2 | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.812); catalogued as COSV100996954; called by muse, mutect2
- MPPED1 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769360255, COSV68837885; called by muse, mutect2, varscan2
- MS4A15 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100558977; called by muse, mutect2, varscan2
- MYO1E | c.1804A>T p.R602W | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99896736; called by muse, mutect2, varscan2
- MZT1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761847353, COSV64698085; called by muse, mutect2, varscan2
- NALCN | c.1605C>A p.D535E | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.681); catalogued as COSV99218040; called by muse, mutect2, varscan2
- NFAT5 | c.2630C>G p.S877C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs764512084, COSV100591284; called by muse, mutect2, varscan2
- NFXL1 | c.2004G>T p.L668F | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100217082; called by muse, mutect2, varscan2
- NKX3-2 | c.10C>G p.R4G | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV101220023; called by muse, mutect2, varscan2
- NPAP1 | c.3265C>A p.P1089T | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV61504078, COSV61509167; called by muse, mutect2, varscan2
- NPR2 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 63/110 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100709770; called by muse, mutect2, varscan2
- NUTM1 | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100412633; called by muse, mutect2, varscan2
- OR10A2 | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100225187; called by muse, mutect2, varscan2
- OR2W3 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV100831860; called by muse, mutect2, varscan2
- OR4C13 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782667631, COSV73648787, COSV73648916; called by muse, mutect2, varscan2
- OR52I2 | c.81G>T p.M27I | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100443024; called by muse, mutect2, varscan2
- OR5D14 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59456295, COSV99045924; called by muse, mutect2, varscan2
- OR5P3 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100103281; called by muse, mutect2, varscan2
- OR8J1 | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100275238, COSV57317641; called by muse, mutect2, varscan2
- OTOGL | c.5266G>C p.V1756L (on ENST00000547103; = p.V1747L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV100087971; called by muse, mutect2, varscan2
- PAPPA2 | c.204T>A p.F68L | Missense Mutation (SNP) | VAF 92/291 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.935); catalogued as COSV100867212; called by muse, mutect2, varscan2
- PARD6G | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV100783482; called by muse, mutect2, varscan2
- PATE1 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV59824144, COSV99986261; called by muse, mutect2, varscan2
- PATJ | c.1825G>T p.G609C | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100335097; called by muse, mutect2, varscan2
- PBXIP1 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 147/482 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100870132; called by muse, mutect2, varscan2
- PCDHB6 | c.1607C>A p.S536Y | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV50698036, COSV99171557; called by muse, mutect2, varscan2
- PDGFRA | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs751618661, COSV57269720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDILT | c.1607C>A p.P536H | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100199863, COSV99043636; called by muse, mutect2, varscan2
- PLCH2 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.411); catalogued as COSV99617236; called by muse, mutect2, varscan2
- POU2F2 | c.954+1G>T p.X318_splice (on ENST00000526816 / NM_001207025.3; = p.X302_splice on NM_002698.5) | Splice Site (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100657568; called by muse, mutect2, varscan2
- PPP3CA | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548076, COSV59921233; called by muse, mutect2, varscan2
- PRCP | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100476514; called by muse, mutect2, varscan2
- PRDM9 | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99691349; called by muse, mutect2, varscan2
- PRKDC | c.4691C>G p.S1564* | Nonsense Mutation (SNP) | VAF 72/205 reads (35%) | catalogued as COSV100043171; called by muse, mutect2, varscan2
- PRKN | c.738C>A p.S246R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV100631487, COSV58215205; called by muse, mutect2
- PSG7 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs549369260, COSV101343349; called by muse, mutect2, varscan2
- PSG9 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.107); catalogued as COSV52484203; called by muse, mutect2, varscan2
- PSMA1 | c.302G>T p.R101I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV101123700; called by muse, mutect2, varscan2
- PSMD11 | c.1146G>T p.E382D | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99912663; called by muse, varscan2
- PXDNL | c.181A>T p.R61* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as COSV100686656; called by muse, mutect2, varscan2
- PZP | c.3680C>A p.P1227Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99739669; called by muse, mutect2, varscan2
- R3HDM1 | c.1558G>T p.G520* | Nonsense Mutation (SNP) | VAF 23/151 reads (15%) | catalogued as COSV99926881; called by muse, mutect2, varscan2
- RALA | c.596T>A p.I199N | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.296); catalogued as COSV99143507; called by muse, mutect2, varscan2
- RBM14 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 33/97 reads (34%) | catalogued as COSV100036993; called by muse, mutect2, varscan2
- RGS1 | c.137T>C p.F46S | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV100817587; called by muse, mutect2, varscan2
- RYR1 | c.9077G>C p.G3026A | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.294); catalogued as COSV100617120; called by muse, mutect2, varscan2
- RYR2 | c.14507G>A p.G4836E | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100773139; called by muse, mutect2, varscan2
- RYR2 | c.14749A>T p.N4917Y | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100773141; called by muse, mutect2, varscan2
- SALL3 | c.2462C>G p.P821R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101610066; called by muse, mutect2, varscan2
- SCN5A | c.3279G>T p.R1093S (on ENST00000333535 / NM_198056.3; = p.R1092S on NM_000335.5) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.025); catalogued as rs1225014803, COSV100350475; called by muse, mutect2, varscan2
- SDK2 | c.2633G>A p.G878E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101168764; called by muse, mutect2, varscan2
- SEC16A | c.5632G>T p.V1878F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99260296; called by muse, mutect2, varscan2
- SERPINB4 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100346018, COSV61984604; called by muse, mutect2
- SERPINF1 | c.1019C>A p.S340* | Nonsense Mutation (SNP) | VAF 65/182 reads (36%) | catalogued as COSV99629002; called by muse, mutect2, varscan2
- SHANK1 | c.6352C>A p.Q2118K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV99522155; called by muse, mutect2, varscan2
- SLAMF6 | c.548G>T p.W183L | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100924950; called by muse, mutect2, varscan2
- SLC18A1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99368984; called by muse, mutect2, varscan2
- SLC18A2 | c.1055C>A p.A352E | Missense Mutation (SNP) | VAF 71/122 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100042120; called by muse, mutect2, varscan2
- SLC22A9 | c.1083C>A p.N361K | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.296); catalogued as COSV99655406; called by muse, mutect2, varscan2
- SLC6A11 | c.1083C>G p.Y361* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99595075; called by muse, mutect2, varscan2
- SLC8A2 | c.1330T>C p.Y444H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99370347; called by muse, mutect2, varscan2
- SLC9A3 | c.862G>T p.G288C | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99376712; called by muse, mutect2, varscan2
- SMC1B | c.299-1G>C p.X100_splice | Splice Site (SNP) | VAF 28/90 reads (31%) | catalogued as COSV100663551; called by muse, mutect2, varscan2
- SOX3 | c.546C>A p.D182E | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.398); catalogued as COSV100983768; called by muse, mutect2, varscan2
- SP7 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100382123; called by muse, mutect2, varscan2
- SPAM1 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.029); catalogued as COSV99773548; called by muse, mutect2, varscan2
- SPCS3 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV101543713; called by muse, varscan2
- SPINK5 | c.207A>C p.I69= | Splice Region (SNP) | VAF 36/64 reads (56%) | catalogued as COSV99807459; called by muse, mutect2, varscan2
- SPOCK3 | c.582C>G p.S194R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100694167; called by muse, mutect2, varscan2
- SRRM2 | c.2387G>C p.R796P | Missense Mutation (SNP) | VAF 91/498 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.481); catalogued as COSV100070806, COSV100071577; called by muse, mutect2, varscan2
- STAB2 | c.3386C>T p.P1129L | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101186391; called by muse, mutect2, varscan2
- TAF5 | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100674769, COSV100674784; called by muse, mutect2, varscan2
- TAF9B | c.598G>C p.A200P | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs1557249511, COSV100540774; called by muse, mutect2, varscan2
- TCHHL1 | c.1050G>T p.L350F | Missense Mutation (SNP) | VAF 47/346 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.047); catalogued as COSV100916560; called by muse, mutect2, varscan2
- TENT5D | c.660C>A p.H220Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100382999; called by muse, mutect2
- TFDP3 | c.303C>G p.N101K | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100033564; called by muse, mutect2, varscan2
- TIMD4 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1317417880, COSV50855655; called by muse, mutect2, varscan2
- TMC3 | c.695T>A p.L232Q | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100846053; called by muse, mutect2, varscan2
- TPR | c.5830A>G p.I1944V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.456); catalogued as COSV100824271; called by muse, mutect2, varscan2
- TPTE | c.305T>A p.V102D (on ENST00000618007 / NM_199261.4; = p.V84D on NM_199259.4) | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs558436767; called by muse, mutect2, varscan2
- TRAF3IP2 | c.700C>G p.Q234E | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV100389881, COSV100389930; called by muse, mutect2, varscan2
- TRAK2 | c.2314G>T p.A772S | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100217188; called by muse, mutect2, varscan2
- TRIM48 | c.103A>C p.M35L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs112137140, COSV101338368, COSV101338378; called by mutect2, varscan2
- TRPC1 | c.863A>G p.H288R (on ENST00000476941 / NM_001251845.2; = p.H254R on NM_003304.4) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV99859390; called by muse, mutect2, varscan2
- TRPM7 | c.2337G>T p.K779N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100540383; called by muse, mutect2, varscan2
- TSHZ1 | c.2309C>T p.P770L (on ENST00000580243 / NM_001308210.2; = p.P725L on NM_005786.6) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59016735; called by muse, mutect2, varscan2
- TTN | c.83824A>G p.M27942V (on ENST00000591111; = p.M20518V on NM_003319.4) | Missense Mutation (SNP) | VAF 30/156 reads (19%) | PolyPhen benign (0); catalogued as rs377535587; called by muse, mutect2, varscan2
- TTN | c.6863G>T p.C2288F (on ENST00000591111; = p.C2242F on NM_003319.4) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | PolyPhen probably damaging (0.931); catalogued as COSV100632436; called by muse, mutect2, varscan2
- UBE2A | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV100660544; called by muse, mutect2, varscan2
- UNC79 | c.4300C>T p.Q1434* (on ENST00000393151 / NM_001346218.2; = p.Q1257* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as COSV99829995; called by muse, mutect2, varscan2
- UNKL | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100061810; called by muse, mutect2
- URAD | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV100229642; called by muse, mutect2, varscan2
- VPS13D | c.8821C>T p.R2941* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | catalogued as COSV99169679; called by muse, mutect2, varscan2
- WASHC2C | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.162); catalogued as COSV100314251; called by muse, mutect2, varscan2
- WDR19 | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.048); catalogued as rs184326673; called by muse, mutect2
- WDR75 | c.2254G>T p.V752L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100134486; called by muse, mutect2, varscan2
- ZFHX4 | c.2547C>A p.F849L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1250836707, COSV99268292; called by muse, mutect2
- ZFHX4 | c.7025A>C p.D2342A | Missense Mutation (SNP) | VAF 102/255 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV50694901, COSV99268304; called by muse, mutect2, varscan2
- ZFP30 | c.1214T>A p.I405N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV100666095; called by muse, mutect2, varscan2
- ZNF479 | c.1016A>C p.N339T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100483104; called by muse, mutect2, varscan2
- ZNF480 | c.303G>T p.R101S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.88); PolyPhen benign (0.081); catalogued as COSV100574336; called by muse, mutect2, varscan2
- ZNF536 | c.3314G>T p.C1105F | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs765268120, COSV100836034; called by muse, mutect2, varscan2
- ZNF586 | c.1184A>T p.H395L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101197752; called by muse, mutect2, varscan2
- ZNF683 | c.1099A>T p.K367* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as rs1440332092, COSV100853752; called by muse, mutect2, varscan2
- ZNF804A | c.3597C>A p.H1199Q | Missense Mutation (SNP) | VAF 100/347 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV100170399, COSV56434069; called by muse, mutect2, varscan2
- ZNF93 | c.757G>T p.G253* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as COSV100652263, COSV100652448; called by muse, mutect2, varscan2
- ZP1 | c.733T>A p.C245S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99612865; called by muse, mutect2, varscan2
- ZP3 | c.713+1G>C p.X238_splice (on ENST00000394857 / NM_001110354.2; = p.X187_splice on NM_007155.6) | Splice Site (SNP) | VAF 28/149 reads (19%) | catalogued as COSV100334733; called by muse, mutect2, varscan2
- ZP4 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV63911790; called by muse, mutect2, varscan2
- ZSCAN20 | c.2369G>T p.G790V | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100792753; called by muse, mutect2, varscan2
- ADGRD1 | c.249del p.L84Sfs*71 | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | called by mutect2, pindel, varscan2
- ADGRF5 | c.3623del p.K1208Sfs*64 | Frame Shift Del (DEL) | VAF 55/193 reads (28%) | called by mutect2, pindel, varscan2
- CMTR2 | c.1531del p.C511Afs*6 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by pindel, varscan2
- FBP1 | c.568-2del p.X190_splice | Splice Site (DEL) | VAF 15/82 reads (18%) | called by pindel, varscan2*
- FOXD4L5 | c.913C>A p.L305I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.036); called by mutect2, varscan2
- HADH | c.225G>T p.R75S | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- IGKV3-20 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MAML2 | c.3263del p.P1088Lfs*19 | Frame Shift Del (DEL) | VAF 15/120 reads (13%) | called by mutect2, pindel, varscan2
- MCM4 | c.1774del p.E592Nfs*55 | Frame Shift Del (DEL) | VAF 6/69 reads (9%) | called by mutect2, pindel
- MLKL | c.1085del p.G362Efs*30 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- MUC2 | c.2305G>T p.A769S | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- NLRC5 | c.684del p.K229Rfs*22 | Frame Shift Del (DEL) | VAF 47/253 reads (19%) | called by mutect2, pindel, varscan2
- OR13C9 | c.945C>G p.F315L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- OR13G1 | c.100del p.V34Wfs*28 | Frame Shift Del (DEL) | VAF 28/109 reads (26%) | called by mutect2, pindel, varscan2
- PIBF1 | c.553-5_562del p.X185_splice | Splice Site (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel
- TPTE | c.904A>T p.I302F (on ENST00000618007 / NM_199261.4; = p.I284F on NM_199259.4) | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIM47 | c.1114dup p.M372Nfs*31 | Frame Shift Ins (INS) | VAF 39/127 reads (31%) | called by mutect2, pindel, varscan2
- WRNIP1 | c.96del p.N33Tfs*48 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- ZC3HAV1 | c.1529_1530del p.E510Gfs*5 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | called by pindel, varscan2
- ZNF292 | c.5153dup p.L1719Ffs*6 | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- ACTN4 | c.747G>T p.T249= | Silent (SNP) | VAF 55/295 reads (19%) | catalogued as COSV99400789; called by muse, mutect2, varscan2
- ADAM15 | c.660G>T p.V220= | Silent (SNP) | VAF 23/207 reads (11%) | catalogued as COSV99665388; called by muse, varscan2
- AOC3 | c.2094G>T p.G698= | Silent (SNP) | VAF 40/214 reads (19%) | catalogued as rs377171742; called by muse, mutect2, varscan2
- CCHCR1 | c.1644C>T p.A548= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV99459316; called by muse, mutect2, varscan2
- CDH8 | c.33T>C p.D11= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as COSV100184357; called by muse, mutect2, varscan2
- CHMP4C | c.345G>A p.A115= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs140893589; called by muse, mutect2, varscan2
- CHRD | c.2043G>T p.V681= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV99200852; called by muse, mutect2, varscan2
- CNTNAP2 | c.274C>A p.R92= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs747286104, COSV100666387, COSV100673833; called by muse, mutect2, varscan2
- CNTNAP2 | c.792A>T p.S264= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as COSV100673364, COSV62265723; called by muse, mutect2, varscan2
- COL14A1 | c.2790T>G p.V930= | Silent (SNP) | VAF 12/196 reads (6%) | catalogued as COSV99920847; called by muse, mutect2
- COL5A1 | c.1407C>T p.G469= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs998546530, COSV100880622; called by muse, mutect2, varscan2
- CROCC | c.525G>T p.R175= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100978431; called by muse, mutect2, varscan2
- CTRL | c.108C>T p.N36= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs146079104; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYP2C19 | c.879C>T p.D293= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as COSV100990639; called by muse, mutect2, varscan2
- CYP2F1 | c.1002C>A p.R334= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100463032, COSV58527542; called by muse, mutect2, varscan2
- DUOX2 | c.2952C>T p.A984= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as COSV101199911; called by muse, mutect2, varscan2
- ESRRG | c.339G>A p.Q113= | Silent (SNP) | VAF 63/256 reads (25%) | catalogued as COSV100753981; called by muse, mutect2, varscan2
- HIVEP1 | c.6729G>T p.T2243= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV101045792; called by muse, mutect2, varscan2
- HLCS | c.1170A>T p.S390= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV100358640; called by muse, mutect2, varscan2
- ITGA4 | c.1635A>C p.T545= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV99276858; called by muse, mutect2, varscan2
- LVRN | c.2493T>A p.I831= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100773699; called by muse, mutect2, varscan2
- LY6H | c.417G>A p.G139= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs759590027, COSV100713949; called by muse, mutect2
- MAPK10 | c.129G>T p.A43= (on ENST00000359221 / NM_001351625.2; = p.A81= on NM_002753.5) | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV100175529, COSV60374911; called by muse, mutect2, varscan2
- MCM8 | c.75G>A p.G25= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs1568565006, COSV99177629; called by muse, mutect2, varscan2
- MEIS1 | c.96C>A p.S32= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs769973553, COSV99715852; called by muse, mutect2, varscan2
- MRC1 | c.672G>T p.P224= | Silent (SNP) | VAF 93/166 reads (56%) | called by muse, mutect2, varscan2
- MUC20 | c.1539C>T p.P513= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs779786660, COSV100291539; called by muse, mutect2, varscan2
- MYH6 | c.5712G>A p.E1904= | Silent (SNP) | VAF 51/196 reads (26%) | catalogued as COSV100198157, COSV100198216; called by muse, mutect2, varscan2
- MYO16 | c.3867C>T p.L1289= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as rs148448924; called by muse, mutect2, varscan2
- MYO3A | c.1551C>A p.I517= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99781754; called by muse, mutect2, varscan2
- NDUFB11 | c.270C>A p.V90= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99333389; called by muse, mutect2
- NRXN2 | c.2172G>T p.R724= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as COSV99636065; called by muse, mutect2, varscan2
- OR14K1 | c.435G>T p.L145= | Silent (SNP) | VAF 22/152 reads (14%) | catalogued as COSV51722046, COSV99315514; called by muse, mutect2, varscan2
- OR2T1 | c.231G>C p.V77= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as COSV100822359; called by muse, mutect2
- OR2W3 | c.411C>T p.N137= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV100831858; called by muse, mutect2, varscan2
- OR4P4 | c.150C>T p.T50= | Silent (SNP) | VAF 51/185 reads (28%) | catalogued as COSV100111878, COSV58921848; called by muse, mutect2, varscan2
- OR6K2 | c.255G>T p.L85= | Silent (SNP) | VAF 26/159 reads (16%) | catalogued as COSV100656906; called by muse, mutect2, varscan2
- PGA5 | c.954C>T p.P318= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs756526706, COSV100409314, COSV56715568; called by muse, varscan2
- PHKA1 | c.627G>C p.L209= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV100263985; called by muse, mutect2, varscan2
- POLA1 | c.1692C>A p.V564= | Silent (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- POU6F2 | c.1207C>T p.L403= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as rs770670204, COSV101302885; called by muse, mutect2, varscan2
- PRDM10 | c.1662G>T p.R554= | Silent (SNP) | VAF 79/248 reads (32%) | catalogued as COSV100457061; called by muse, mutect2, varscan2
- PRRX2 | c.387C>T p.P129= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV100991212; called by muse, varscan2
- PRSS35 | c.1047G>T p.G349= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as COSV100864162; called by muse, mutect2
- ROR2 | c.336G>C p.R112= | Silent (SNP) | VAF 35/162 reads (22%) | catalogued as COSV100996136; called by muse, mutect2, varscan2
- SDHD | c.78C>T p.V26= | Silent (SNP) | VAF 26/191 reads (14%) | catalogued as COSV99736704; called by muse, mutect2, varscan2
- SLC28A1 | c.1743G>T p.L581= | Silent (SNP) | VAF 36/60 reads (60%) | catalogued as COSV99723623; called by muse, mutect2, varscan2
- SOCS4 | c.1077G>T p.G359= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV100216384, COSV100216398; called by muse, mutect2, varscan2
- SRC | c.1485C>T p.H495= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs979391675, COSV100658247, COSV62441234; called by muse, mutect2, varscan2
- STX1B | c.483C>T p.N161= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as rs1185520900, COSV53060163, COSV99288357; called by muse, mutect2, varscan2
- TFAP2D | c.1014C>A p.I338= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as rs1291867005, COSV99148037; called by muse, mutect2, varscan2
- TFEB | c.1212C>A p.G404= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV100026482; called by muse, mutect2, varscan2
- TRIO | c.4899C>T p.S1633= | Silent (SNP) | VAF 76/369 reads (21%) | catalogued as rs1421602318, COSV100711041; called by muse, mutect2, varscan2
- TRPM2 | c.1185G>A p.T395= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs371239755; called by muse, mutect2, varscan2
- TTN | c.44913C>T p.L14971= (on ENST00000591111; = p.L7547= on NM_003319.4) | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100632434; called by muse, mutect2, varscan2
- TTN | c.658C>A p.R220= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs748313513, COSV100632438; called by muse, mutect2, varscan2
- TUBGCP6 | c.4506C>T p.A1502= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs199819496, COSV99956434; called by muse, mutect2, varscan2
- USP11 | c.2811G>C p.L937= (on ENST00000218348; = p.L894= on NM_001371072.1) | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV99511203; called by muse, mutect2
- ZFHX4 | c.3246C>A p.L1082= | Silent (SNP) | VAF 90/265 reads (34%) | catalogued as COSV99268299; called by muse, mutect2, varscan2
- ZMYM3 | c.42C>A p.T14= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100078435; called by muse, mutect2, varscan2
- ZNF536 | c.3726G>A p.Q1242= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100836035, COSV62823167; called by muse, mutect2, varscan2
- ZNF687 | c.1296C>T p.T432= | Silent (SNP) | VAF 56/121 reads (46%) | catalogued as COSV99650227; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827070 C>A | 3'Flank (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851955 G>A | 3'Flank (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+11552G>T | Intron (SNP) | VAF 30/72 reads (42%) | catalogued as COSV100457009; called by muse, mutect2, varscan2
- EIF4A1 | c.514+177C>T | Intron (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99549264; called by muse, mutect2, varscan2
- GABRA3 | c.-26-27676C>A | Intron (SNP) | VAF 5/64 reads (8%) | catalogued as COSV100943482; called by muse, mutect2
- LINC01588 | n.910C>T | RNA (SNP) | VAF 61/120 reads (51%) | called by muse, mutect2, varscan2
- MACROD2 | c.418+165044_418+165047del | Intron (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- MIR513A2 | n.46G>T | RNA (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- RN7SL545P | chr15:22431964 C>A | 5'Flank (SNP) | VAF 40/682 reads (6%) | catalogued as rs753808667; called by muse, mutect2
- RPL23AP82 | n.679C>T | RNA (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
